TCGA case TCGA-61-2610 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1098441d-fb10-4590-a302-0a7cc2332798

Demographics
Sex at birth: female; Race: white; Age at index: 61 years; Vital status: Dead; Days to death: 1,579 days (4.3 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 61.5 years (22,481 days); Year of diagnosis: 1998; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Residual disease: R1.
   Pathology details: Residual tumor measurement: 11-20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 357 days; Number of cycles: 12; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment start: 439 days (1.2 years); Days to treatment end: 530 days (1.5 years); Number of cycles: 4; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 591 days (1.6 years); Days to treatment end: 1,130 days (3.1 years); Number of cycles: 12; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 1,151 days (3.2 years); Days to treatment end: 1,187 days (3.2 years); Treatment dose: 4,000 cGy; Number of fractions: 30; Treatment anatomic sites: Locoregional Site.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 63.0 years (23,005 days); Days to diagnosis: 524 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 554 days (1.5 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (3 entries)
- Day 524 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 524 days (1.4 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,579 days (4.3 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Evidence of recurrence type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-61-2610-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.4.
- Sample TCGA-61-2610-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Longest dimension: 0.6; Intermediate dimension: 0.5; Shortest dimension: 0.3.
  Slide TCGA-61-2610-02A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-61-2610-02A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-61-2610-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.4; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Anatomic organ subdivision: Left; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Toptecan.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 4: Pharmaceutical therapy drug name: Doxil.
- Follow-up form: Treatment outcome first course: Stable Disease; Tumor status: With tumor.

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-61-2610-02A-01R-1139-01: Pairwise comparisons of expression results between platforms HT_HG-U133A and AgilentG4502A_07 suggests that results from this aliquot were from a different patient and therefore these data have been removed.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,579 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,579 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 524 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-61-2610-02A-01D-1134-01): tumor purity 0.87, ploidy 2.01, whole-genome doublings 0.
